Somatic mutation profile of tumor specimen TCGA-B5-A0K7-01A (aliquot TCGA-B5-A0K7-01A-11W-A10C-09) from TCGA case TCGA-B5-A0K7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 64.1 years (23,429 days).
Specimen TCGA-B5-A0K7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5270744-abf2-4523-ba78-d9a09e21da88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K7-10A (Blood Derived Normal), aliquot TCGA-B5-A0K7-10A-02D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0c2b88b-3cb2-41f5-abf4-5647e396852e

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 14, Nonsense Mutation 3, Frame Shift Del 3, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 32/66 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 66/175 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 94/250 reads (38%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACSL6 | c.836C>T p.T279M (on ENST00000379240; = p.T304M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763258364, COSV57300205; called by muse, mutect2, varscan2
- ATP13A4 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55076600; called by muse, mutect2, varscan2
- BPIFB4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as rs763730262, COSV64950801; called by muse, mutect2, varscan2
- CADM3 | c.519C>T p.H173= (on ENST00000368125 / NM_001127173.3; = p.H207= on NM_021189.5) | Splice Region (SNP) | VAF 49/214 reads (23%) | catalogued as rs200132536; called by muse, mutect2, varscan2
- CALN1 | c.569G>A p.R190Q (on ENST00000329008 / NM_001017440.3; = p.R232Q on NM_031468.4) | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122514, COSV61147636; called by muse, mutect2, varscan2
- CCDC86 | c.485A>C p.E162A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV57126583; called by muse, mutect2, varscan2
- CNTN3 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55187763; called by mutect2, varscan2
- CSDE1 | c.530T>G p.M177R (on ENST00000358528 / NM_001007553.3; = p.M146R on NM_007158.6) | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54763532; called by muse, mutect2, varscan2
- CTCF | c.1569C>A p.Y523* | Nonsense Mutation (SNP) | VAF 54/140 reads (39%) | catalogued as COSV50541307, COSV99864201; called by muse, mutect2, varscan2
- FAM133A | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.02); catalogued as rs199711405, COSV59074132; called by muse, mutect2, varscan2
- GPR101 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs143030995, COSV53238063; called by muse, mutect2, varscan2
- IL25 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV59308580; called by muse, mutect2, varscan2
- IQSEC2 | c.2218C>A p.H740N (on ENST00000642864 / NM_001111125.3; = p.H535N on NM_015075.2) | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.265); catalogued as COSV64728603; called by muse, mutect2
- LRRK2 | c.3397A>T p.I1133F | Missense Mutation (SNP) | VAF 127/304 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV54175527; called by muse, mutect2, varscan2
- MANBA | c.2338C>T p.R780C (on ENST00000642252; = p.R734C on NM_005908.4) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs750688426, COSV56963858; called by muse, mutect2, varscan2
- MECP2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1557137821, COSV57657855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METAP1 | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 417/1003 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56443958; called by muse, mutect2, varscan2
- NBPF1 | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 91/552 reads (16%) | catalogued as COSV55324219; called by muse, varscan2
- NEK9 | c.2167A>G p.I723V | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53130688; called by muse, mutect2
- NPC1L1 | c.3625G>A p.V1209M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56931308; called by muse, mutect2, varscan2
- NRK | c.4192C>A p.L1398M | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV54609387; called by muse, mutect2, varscan2
- OR5P3 | c.571del p.H191Mfs*7 | Frame Shift Del (DEL) | VAF 37/126 reads (29%) | catalogued as COSV100103041; called by mutect2, pindel, varscan2
- PCDHA13 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56524837; called by muse, mutect2, varscan2
- PIP4P2 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 145/409 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.983); catalogued as COSV53441585; called by muse, mutect2, varscan2
- PSMD5 | c.908T>A p.M303K | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52962365; called by muse, mutect2, varscan2
- PTEN | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 153/374 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898159, COSV100909436, COSV64306562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.922del p.R308Vfs*9 | Frame Shift Del (DEL) | VAF 120/561 reads (21%) | catalogued as COSV64291569, COSV64310183; called by pindel, varscan2
- RAB8A | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56293479; called by muse, mutect2
- RIPOR1 | c.464G>A p.R155H (on ENST00000379312 / NM_001193522.2; = p.R151H on NM_024519.4) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1270478112, COSV50290812; called by muse, mutect2, varscan2
- RPAP3 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 213/450 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs371796000; called by muse, mutect2, varscan2
- SAMD9L | c.4393C>T p.R1465C | Missense Mutation (SNP) | VAF 141/391 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.528); catalogued as rs181466556, COSV59081134; called by muse, mutect2, varscan2
- SPTBN5 | c.2797C>A p.Q933K | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as rs1336462458; called by muse, mutect2
- UBA6 | c.2855T>G p.F952C | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59181577; called by muse, mutect2, varscan2
- UBE3B | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as COSV55099935; called by muse, mutect2, varscan2
- USP44 | c.2118del p.S707Lfs*26 | Frame Shift Del (DEL) | VAF 48/143 reads (34%) | catalogued as COSV51567983; called by mutect2, pindel, varscan2
- ZNF556 | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV56914799; called by muse, mutect2, varscan2
- ESR1 | c.1244_1252del p.G415_C417del | In Frame Del (DEL) | VAF 78/225 reads (35%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.2388G>A p.P796= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as rs771713358, COSV57612230; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1101G>A p.V367= | Silent (SNP) | VAF 67/184 reads (36%) | catalogued as COSV63439368; called by muse, mutect2, varscan2
- COL11A2 | c.4356C>A p.S1452= (on ENST00000341947 / NM_080680.3; = p.S1345= on NM_080679.2) | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV59504043; called by muse, mutect2
- DHX37 | c.3282G>A p.T1094= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1398408582, COSV58140441; called by muse, mutect2, varscan2
- FAT3 | c.11269T>C p.L3757= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV53188409; called by muse, mutect2, varscan2
- HGS | c.342C>T p.A114= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1255820461, COSV61270857; called by muse, mutect2, varscan2
- MUC16 | c.33402G>T p.G11134= | Silent (SNP) | VAF 149/584 reads (26%) | catalogued as rs1300275156, COSV67502335; called by muse, mutect2, varscan2
- ORM1 | c.144G>A p.S48= | Silent (SNP) | VAF 128/386 reads (33%) | catalogued as rs768349379, COSV52278818; called by muse, mutect2, varscan2
- PCDHA12 | c.1314G>A p.T438= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs1316558090, COSV56475128, COSV56490111; called by muse, mutect2, varscan2
- PCDHGB4 | c.735C>T p.D245= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs369637121, COSV54055567; called by muse, mutect2, varscan2
- POLA1 | c.1614C>T p.V538= | Silent (SNP) | VAF 178/444 reads (40%) | catalogued as COSV66891669; called by muse, mutect2, varscan2
- TINAG | c.156C>T p.F52= | Silent (SNP) | VAF 485/1200 reads (40%) | catalogued as COSV52505058; called by muse, mutect2, varscan2
- TMEM241 | c.315T>G p.A105= | Silent (SNP) | VAF 193/430 reads (45%) | catalogued as COSV67245995; called by muse, mutect2, varscan2
- TNRC18 | c.4815G>C p.S1605= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV68171579; called by muse, mutect2
- SLC41A3 | c.274-5353C>T | Intron (SNP) | VAF 35/86 reads (41%) | catalogued as rs149663130; called by muse, mutect2, varscan2
